Gene-level copy-number profile of tumor specimen TCGA-EE-A2GE-06A from TCGA case TCGA-EE-A2GE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.2 years (19,426 days).
Specimen TCGA-EE-A2GE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.09081350-d32c-45d1-a049-7cef323c4828.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2GE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b16a76d-5c03-4b7e-bc7e-b78d6c4ec86e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 2,349; copy number 2: 11,625; copy number 3: 8,774; copy number 4: 27,375; copy number 5: 6,577; copy number 6: 1,838; copy number 8: 1,176.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2GE-06A-11D-A194-01): tumor purity 0.22, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,096,032–22,559,037, 98 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
